Somatic mutation profile of tumor specimen TCGA-W8-A86G-01A (aliquot TCGA-W8-A86G-01A-21D-A36J-09) from TCGA case TCGA-W8-A86G, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.1 years (24,125 days).
Specimen TCGA-W8-A86G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50a359e9-9dfe-440a-bb8c-086ca7b9c611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W8-A86G-10A (Blood Derived Normal), aliquot TCGA-W8-A86G-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b851f45-d443-44ba-8229-d08b2a0ca70f

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPAST | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622162, HM060056, COSV100188499; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANKRD52 | c.2119C>A p.L707M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99921272; called by muse, mutect2
- DCHS1 | c.2509T>A p.F837I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100201971; called by muse, mutect2, varscan2
- DNAJC21 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100331367, COSV100331458; called by muse, mutect2, varscan2
- ERF | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs368169058; called by muse, mutect2, varscan2
- KDM1A | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100752553, COSV63086434; called by muse, mutect2, varscan2
- KIF3A | c.392T>G p.F131C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101109318; called by muse, mutect2, varscan2
- KLK2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as rs572630957, COSV57571211; called by muse, mutect2, varscan2
- MEGF8 | c.4978G>T p.V1660L (on ENST00000251268 / NM_001271938.2; = p.V1593L on NM_001410.3) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV99235925; called by muse, mutect2, varscan2
- MGST3 | c.347C>G p.A116G | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100903338; called by muse, mutect2, varscan2
- CDH1 | c.568dup p.Y190Lfs*9 | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- MGAT4A | c.259dup p.S87Ffs*3 | Frame Shift Ins (INS) | VAF 40/155 reads (26%) | called by mutect2, pindel, varscan2
- CHRD | c.2166C>T p.Y722= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs766572394, COSV52605082; called by muse, mutect2, varscan2
- KIF4A | c.339G>T p.G113= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as COSV100979489; called by muse, mutect2, varscan2
- MYOM2 | c.2811C>T p.D937= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs745874438, COSV50720223; called by muse, mutect2, varscan2
- RASGRP4 | c.1477C>A p.R493= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV53039900, COSV99384963; called by muse, mutect2, varscan2
- SMC2 | c.1797C>T p.G599= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99658879; called by muse, mutect2, varscan2
- MFRP | chr11:119345903 C>T | 5'Flank (SNP) | VAF 21/63 reads (33%) | catalogued as rs746179158, COSV100793419; called by muse, mutect2, varscan2
